MMRF case MMRF_1100 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/680758e3-654f-4e26-acd3-cb06adcfb6bc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.6 years (25,071 days); ISS stage: I; Days to last known disease status: 1,699 days (4.7 years); Days to last follow up: 1,699 days (4.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 974 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 859 days (2.4 years); Days to treatment end: 947 days (2.6 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 975 days (2.7 years); Days to treatment end: 975 days (2.7 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 975 days (2.7 years); Days to treatment end: 975 days (2.7 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,187 days (3.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,384 days (3.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19: M Protein 4.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.198 mg/dL; Immunoglobulin G 66.7 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 3.44 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 10.9 g/dL; Glucose 4.62 mmol/L; C-Reactive Protein 0.06 mg/dL.
- Day 73 (ECOG 1): M Protein 1.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.838 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 4.51 mmol/L.
- Day 184: M Protein 0.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.76 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 3.52 mmol/L.
- Day 249: M Protein 0.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 4.68 mmol/L.
- Day 358 (ECOG 0): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.79 mmol/L.
- Day 452 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 554 (ECOG 0): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.48 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 617 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.34 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 6.16 mmol/L.
- Day 710 (ECOG 0): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.08 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 3.01 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 4.62 mmol/L.
- Day 794 (ECOG 0): M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 2.78 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 6.33 mmol/L.
- Day 859 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 7.2 g/dL; Glucose 6.11 mmol/L.
- Day 960 (ECOG 1): M Protein 1.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 21.7 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 3.02 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 5.06 mmol/L.
- Day 1,079 (ECOG 0): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.719 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.65 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.06 mmol/L.
- Day 1,164 (ECOG 0): M Protein 1.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 20.8 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7.7 g/dL; Glucose 5.28 mmol/L.
- Day 1,244 (ECOG 0): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.393 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.082 mg/dL; Immunoglobulin G 9.14 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 1,331: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.764 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.166 mg/dL; Immunoglobulin G 5.3 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.49 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 7.04 mmol/L.
- Day 1,412 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.874 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.206 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 1,524 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.557 mg/dL; Immunoglobulin G 3.8 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 5.4 g/dL; Glucose 5.12 mmol/L.
- Day 1,627 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.902 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.508 mg/dL; Immunoglobulin G 4.47 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.11 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 1,699: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.671 mg/dL; Immunoglobulin G 3.59 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.75 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.15 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -19: Weight: 81 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1100_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_1100_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
